Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RW, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RW-01A (Primary Tumor).

[page 1 of 2]
Nature of material: Brain

Biopsy:

Macroscopy

Pyramidal portion of brain brain containing spins, measuring 5.0 x 4.5 x 2.7 cm. Cortical surface is brownish, bright, with blood vessels congested. Surgical margins had congested areas. The surface is white, not observing the boundaries between different substances and cortical gray subcortical white.

Microscopy

Histological sections stained with h & e sections showing brain parenchymal viewing neoplasia glial hypercellular, atypical cells incorporated in the nucleus the oval rounded, chromatin coarse. Neoplastic cells arrange up fashion and diffuse infiltrate the normal brain parenchyma, involving neurons. Sattelitis peri-neuronal structures and secondary in cortex, featured in cell aggregation perivascular. There conspicuous network slender pots and branched standard "chicken wire". Analyzed there was in an average 1 figure of mitosis every 10 fields. It was not not observed necrosis or areas of endothelial proliferation microvascular. The immunohistochemistry was intense neoplasms in positive for anti-gfap and s100 protein. Ki-67 was 6%.

Diagnosis:

- Oligodendroglioma, grade II

Notes

- It was not found clear criteria for anaplastic oligodendroglioma diagnosis.

PROFESSIONAL PARTICIPANTS OF REPORT

CBCE ICD-O-3
Oligoastrocytoma, grade II
path 9382/3
Oligodendroglioma, grade II
CBCE 9456/3
Site Brain, supratentorial NOS
path 271.0
Brain NOS
271.9
JW 10/4/13

Per TSS, dx discrepancy from
Stake TCGA turn to be
oligoastrocytoma, grade II. PCR

Diagnosis Synchronous Primary Malignancy	☒	☒

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:

Study/Site:

TCGA Brain lower grade glioma -

(Brain Lower Grade Glioma)

Event:

PathDiscrepancy

Interviewer:

Person ID:

N/A

Age:

N/A

Date of Birth:

Sex:

M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report

Oligodendroglioma
grade II

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF

Oligoastrocytoma
grade II

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

wrote in TCGA Pathologic Diagnosis Discrepancy Form: "This case was initially seen by other pathologist. Even though is quite subjective, in my opinion, there is an astrocytic component (p53+ at IHC)".

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file 771f4090-e507-410c-8b46-10c37eafc65c (TCGA-TQ-A7RW.CD826C0A-8057-4BD6-A79A-51277F0E09A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).